Gene-level copy-number profile of tumor specimen MP2PRT-PAUEJC-TMP1-A from MP2PRT case MP2PRT-PAUEJC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,913 days).
Specimen MP2PRT-PAUEJC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9a1c441e-f638-402a-8684-9da2d8ab3ef8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUEJC-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/0c761dec-7a81-423b-b5cc-38b16d6ebcbc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 228; copy number 1: 22; copy number 2: 932; copy number 3: 1,564; copy number 4: 54,934; copy number 5: 682; copy number 6: 16.

Homozygous deletions (total copy number 0; autosomes only): 228 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 41 genes (within-gene range 0–4): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–4): TRGC1.
- chr7:38,273,587–38,311,808, 6 genes (within-gene range 0–4): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,656,701–142,802,748, 26 genes: TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–4): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,511,024, 23 genes (within-gene range 0–4): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.
- chr14:106,584,718–106,593,347, 3 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52, IGHV3-53.
- chr22:22,219,647–22,245,515, 4 genes: IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
